Somatic mutation profile of tumor specimen 0DDIKM from CCDI case PBBNVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,584 days).
Specimen 0DDIKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21491755-f5ae-4ddf-bc4f-f7ba5f447cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDIK9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e58baa57-1e13-4e1d-8f23-d89555ec3421

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.1379C>G p.A460G | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs797045270, COSV51667793; called by muse, mutect2
- DCAF4L1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 24/804 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV60788690; called by muse, mutect2
- PRODH2 | c.30G>A p.S10= | Silent (SNP) | VAF 167/552 reads (30%) | catalogued as rs751098769; called by muse, mutect2, varscan2
- BCL7A | c.-100G>A | 5'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
